Somatic mutation profile of tumor specimen TCGA-23-1118-01A (aliquot TCGA-23-1118-01A-01W-0488-09) from TCGA case TCGA-23-1118, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 45.1 years (16,471 days).
Specimen TCGA-23-1118-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fe263539-b397-4f55-9145-b8e9cfbd9298.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-23-1118-10A (Blood Derived Normal), aliquot TCGA-23-1118-10A-01W-0486-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/010e75f4-e7f3-46af-bdad-9fd95364ee92

The open-access MAF lists 85 somatic variants for this specimen: 74 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 60, Silent 10, Nonsense Mutation 5, Splice Site 4, Frame Shift Del 3, In Frame Del 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 48/86 reads (56%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); catalogued as rs28934874, CM012662, CM120847, CM941326, COSV52661698, COSV52676321, COSV52676982, COSV52701855; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AKAP14 | c.341T>A p.I114N | Missense Mutation (SNP) | VAF 54/1038 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.113); catalogued as COSV100538336; called by muse, mutect2
- ASNSD1 | c.985G>T p.G329C | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1036742566, COSV53624598; called by muse, mutect2
- CCDC60 | c.603C>A p.D201E | Missense Mutation (SNP) | VAF 208/725 reads (29%) | SIFT tolerated (0.66); PolyPhen benign (0.168); catalogued as COSV59548797; called by muse, mutect2, varscan2
- CDCP1 | c.2146C>G p.P716A | Missense Mutation (SNP) | VAF 85/691 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV56107418; called by muse, mutect2, varscan2
- CEBPE | c.58T>A p.F20I | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0.135); catalogued as COSV52830557; called by muse, mutect2, varscan2
- CKAP5 | c.1339-1G>A p.X447_splice | Splice Site (SNP) | VAF 134/363 reads (37%) | catalogued as COSV56372787; called by muse, mutect2, varscan2
- CNTN1 | c.2675C>A p.P892Q | Missense Mutation (SNP) | VAF 102/344 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV61644253; called by muse, mutect2, varscan2
- CORIN | c.1400C>G p.P467R | Missense Mutation (SNP) | VAF 55/161 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs193921036, COSV56691476; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CRBN | c.355A>G p.T119A | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV51642375; called by muse, mutect2, varscan2
- DNAH10 | c.1421+2T>C p.X474_splice (on ENST00000409039; = p.X413_splice on NM_207437.3) | Splice Site (SNP) | VAF 9/80 reads (11%) | catalogued as COSV101292350; called by muse, mutect2
- EVL | c.10C>T p.Q4* (on ENST00000402714 / NM_001330221.2; = p.Q6* on NM_016337.3) | Nonsense Mutation (SNP) | VAF 10/156 reads (6%) | catalogued as COSV101233088; called by muse, mutect2
- FGF2 | c.864C>G p.S288R | Missense Mutation (SNP) | VAF 66/231 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); catalogued as COSV52652298; called by muse, mutect2, varscan2
- GALNT1 | c.1198G>A p.V400I | Missense Mutation (SNP) | VAF 91/169 reads (54%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV52454448; called by muse, mutect2, varscan2
- GLYATL2 | c.851A>T p.H284L | Missense Mutation (SNP) | VAF 19/176 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV99780418; called by muse, mutect2, varscan2
- GPR139 | c.886G>T p.A296S | Missense Mutation (SNP) | VAF 72/176 reads (41%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.714); catalogued as COSV58504489; called by muse, varscan2
- GPR139 | c.766C>T p.P256S | Missense Mutation (SNP) | VAF 48/132 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0.164); catalogued as COSV58504497; called by muse, varscan2
- HSD3B1 | c.1045G>T p.A349S | Missense Mutation (SNP) | VAF 50/207 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV52491847; called by muse, mutect2, varscan2
- HUNK | c.847A>T p.N283Y | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV99528640; called by muse, mutect2
- HYDIN | c.1784T>A p.I595N | Missense Mutation (SNP) | VAF 36/158 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.323); catalogued as COSV55496011; called by muse, mutect2, varscan2
- IGHV3-72 | c.260G>A p.G87D | Missense Mutation (SNP) | VAF 18/489 reads (4%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.629); catalogued as COSV101455371; called by muse, mutect2
- IGSF22 | c.2695+1G>A p.X899_splice (on ENST00000319338; = p.X1000_splice on NM_173588.4) | Splice Site (SNP) | VAF 14/129 reads (11%) | catalogued as COSV55011671; called by muse, mutect2, varscan2
- INSRR | c.479C>G p.P160R | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.416); catalogued as COSV63876448; called by muse, mutect2, varscan2
- ITGAX | c.1603A>C p.K535Q | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.012); catalogued as COSV51650068; called by muse, mutect2, varscan2
- KMT5B | c.2008C>A p.P670T | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.099); catalogued as COSV58569015; called by muse, mutect2, varscan2
- LAMB3 | c.3193G>T p.E1065* | Nonsense Mutation (SNP) | VAF 28/91 reads (31%) | catalogued as COSV50524847; called by muse, mutect2, varscan2
- LILRA2 | c.535A>G p.I179V | Missense Mutation (SNP) | VAF 30/200 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV52195659; called by muse, mutect2, varscan2
- MARS1 | c.1970C>T p.A657V | Missense Mutation (SNP) | VAF 36/207 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.177); catalogued as COSV56257902; called by muse, mutect2, varscan2
- ME1 | c.1462C>A p.Q488K | Missense Mutation (SNP) | VAF 63/162 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.109); catalogued as rs879135160, COSV63841917; called by muse, mutect2, varscan2
- MELK | c.1540C>T p.H514Y | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV53201670; called by muse, mutect2, varscan2
- MYO18B | c.6258A>C p.E2086D | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.024); catalogued as COSV59127042; called by muse, mutect2, varscan2
- NCOA3 | c.1076A>T p.D359V | Missense Mutation (SNP) | VAF 39/329 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.082); catalogued as COSV59072233; called by muse, mutect2, varscan2
- NLRP8 | c.2381+1G>T p.X794_splice | Splice Site (SNP) | VAF 34/96 reads (35%) | catalogued as COSV52592349; called by muse, mutect2
- OR10H5 | c.122G>A p.G41D | Missense Mutation (SNP) | VAF 62/559 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58278979; called by muse, mutect2, varscan2
- PELI1 | c.1043G>A p.G348E | Missense Mutation (SNP) | VAF 84/302 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100735145; called by muse, mutect2, varscan2
- PENK | c.646A>G p.R216G | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59242835; called by muse, mutect2, varscan2
- PGLYRP3 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 124/441 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.355); catalogued as COSV51952205; called by muse, varscan2
- PKP4 | c.513G>C p.K171N | Missense Mutation (SNP) | VAF 21/197 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.711); catalogued as COSV67678789; called by muse, mutect2, varscan2
- PLD5 | c.1025T>G p.I342S (on ENST00000442594; = p.I280S on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV59163016; called by muse, mutect2, varscan2
- PNLIPRP3 | c.1243A>T p.S415C | Missense Mutation (SNP) | VAF 32/261 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV65049365, COSV65049541; called by muse, mutect2, varscan2
- RBL2 | c.2365C>G p.L789V | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.038); catalogued as COSV100043803; called by muse, mutect2
- RBL2 | c.3269G>T p.S1090I | Missense Mutation (SNP) | VAF 15/202 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); catalogued as COSV50885050; called by muse, mutect2
- RTN1 | c.887C>A p.T296N | Missense Mutation (SNP) | VAF 46/269 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.13); catalogued as COSV50722807; called by muse, mutect2, varscan2
- SH2D1A | c.233G>C p.R78P | Missense Mutation (SNP) | VAF 23/752 reads (3%) | SIFT tolerated (0.26); PolyPhen probably damaging (1); catalogued as COSV63579679; called by muse, mutect2
- SLC22A14 | c.730A>T p.I244F | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.374); catalogued as rs542959928, COSV99828286; called by muse, mutect2
- SLC6A6 | c.1630G>T p.G544W | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.112); catalogued as COSV100692252; called by muse, mutect2
- SRGAP2 | c.2771C>A p.A924E (on ENST00000624873 / NM_001170637.4; = p.A925E on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.593); catalogued as COSV55334702, COSV55341840; called by muse, mutect2
- STARD13 | c.368T>A p.V123E (on ENST00000336934 / NM_001243476.3; = p.V5E on NM_052851.3) | Missense Mutation (SNP) | VAF 42/184 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV55235319; called by muse, mutect2, varscan2
- SYNGAP1 | c.1063G>A p.G355R | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53385494; called by muse, mutect2, varscan2
- TASOR | c.2299G>C p.D767H (on ENST00000355628 / NM_001365636.2; = p.D371H on NM_015224.3) | Missense Mutation (SNP) | VAF 71/129 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as COSV62929288; called by muse, mutect2, varscan2
- THBS1 | c.508G>T p.D170Y | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as COSV99528078; called by muse, mutect2, varscan2
- THBS1 | c.509A>T p.D170V | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.059); catalogued as COSV99528080; called by muse, mutect2, varscan2
- TMEM132B | c.1293G>T p.L431F | Missense Mutation (SNP) | VAF 51/256 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV54765680; called by muse, mutect2, varscan2
- TNRC6C | c.1696G>T p.D566Y | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV56951368; called by muse, mutect2
- TWNK | c.310A>T p.I104F | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV52971137; called by muse, mutect2, varscan2
- VNN1 | c.1457C>G p.S486* | Nonsense Mutation (SNP) | VAF 106/187 reads (57%) | catalogued as COSV63390762; called by muse, mutect2, varscan2
- WDR53 | c.349G>T p.A117S | Missense Mutation (SNP) | VAF 26/264 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.02); catalogued as COSV100218105; called by muse, mutect2
- ZKSCAN1 | c.578G>A p.R193Q | Missense Mutation (SNP) | VAF 49/92 reads (53%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs148037051; called by muse, mutect2, varscan2
- ZNF222 | c.252A>C p.Q84H | Missense Mutation (SNP) | VAF 93/166 reads (56%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.867); catalogued as rs771197669, COSV51827954; called by muse, mutect2, varscan2
- ZNF649 | c.56G>A p.W19* | Nonsense Mutation (SNP) | VAF 44/336 reads (13%) | catalogued as COSV61617383; called by muse, mutect2, varscan2
- ZNF813 | c.1516C>T p.R506W | Missense Mutation (SNP) | VAF 75/278 reads (27%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.894); catalogued as rs199775956; called by muse, mutect2, varscan2
- ZSWIM3 | c.272T>A p.L91Q | Missense Mutation (SNP) | VAF 90/148 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54850507; called by muse, mutect2, varscan2
- APOB | c.2087G>A p.G696D | Missense Mutation (SNP) | VAF 8/194 reads (4%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.911); called by muse, mutect2
- CHAF1A | c.1906G>T p.V636L | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- GGCX | c.459_472del p.D153Efs*33 | Frame Shift Del (DEL) | VAF 33/101 reads (33%) | called by mutect2, pindel, varscan2
- IGSF1 | c.442_474del p.V148_D158del | In Frame Del (DEL) | VAF 30/129 reads (23%) | called by mutect2, pindel
- ITGB4 | c.432_451del p.D144Efs*38 | Frame Shift Del (DEL) | VAF 12/19 reads (63%) | called by mutect2, varscan2
- KCNT2 | c.3404T>A p.L1135H | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); called by mutect2, varscan2
- LANCL2 | c.789_805del p.H264Lfs*25 | Frame Shift Del (DEL) | VAF 6/38 reads (16%) | called by mutect2, varscan2
- PCGF6 | c.609G>T p.E203D | Missense Mutation (SNP) | VAF 11/120 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.621); called by muse, mutect2
- PLOD1 | c.1800C>A p.D600E | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- STIM1 | c.336T>G p.D112E | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2
- TOP2A | c.613G>T p.E205* | Nonsense Mutation (SNP) | VAF 1005/3423 reads (29%) | called by muse, varscan2
- ZMYM2 | c.461_493del p.D154_K164del | In Frame Del (DEL) | VAF 118/672 reads (18%) | called by mutect2, pindel
- COL17A1 | c.1230G>A p.L410= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as rs1383270577, COSV100793223, COSV62226154; called by muse, mutect2, varscan2
- MED12 | c.3108C>T p.Y1036= | Silent (SNP) | VAF 16/167 reads (10%) | catalogued as COSV100378632; called by muse, mutect2, varscan2
- NPAT | c.2826C>A p.L942= | Silent (SNP) | VAF 131/382 reads (34%) | catalogued as COSV99586139; called by muse, mutect2, varscan2
- PATL1 | c.969C>G p.P323= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as COSV55692080; called by muse, mutect2
- PELI1 | c.1044A>T p.G348= | Silent (SNP) | VAF 84/294 reads (29%) | catalogued as COSV100735143; called by muse, mutect2, varscan2
- RIPK4 | c.2067G>A p.L689= (on ENST00000352483; = p.L641= on NM_020639.3) | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs929029735, COSV60190075; called by muse, mutect2
- SLC14A2 | c.2655G>A p.P885= | Silent (SNP) | VAF 76/391 reads (19%) | catalogued as rs143610580; called by muse, varscan2
- TRIM23 | c.1326T>C p.T442= | Silent (SNP) | VAF 20/274 reads (7%) | catalogued as rs1480934635, COSV51553909; called by muse, mutect2
- TRRAP | c.10074G>T p.V3358= (on ENST00000359863 / NM_001244580.1; = p.V3329= on NM_003496.3) | Silent (SNP) | VAF 51/171 reads (30%) | catalogued as COSV62852055; called by muse, mutect2, varscan2
- ZNF687 | c.3579G>A p.L1193= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as COSV99649890; called by muse, mutect2, varscan2
- PKD1L2 | n.1258G>T | RNA (SNP) | VAF 14/276 reads (5%) | called by muse, mutect2
